Somatic mutation profile of tumor specimen TARGET-10-PARSSV-09A (aliquot TARGET-10-PARSSV-09A-01D) from TARGET case TARGET-10-PARSSV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,471 days).
Specimen TARGET-10-PARSSV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 763870c2-64e6-4168-b6b1-eaa6af447551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSSV-10A (Blood Derived Normal), aliquot TARGET-10-PARSSV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e62cfa27-9f36-4df8-ab4a-f0383977b167

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Nonsense Mutation 2, 3'Flank 1, Frame Shift Ins 1, 5'Flank 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DRD2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | catalogued as COSV60754633; called by muse, mutect2, varscan2
- ETV6 | c.314dup p.S106Ifs*6 | Frame Shift Ins (INS) | VAF 42/114 reads (37%) | catalogued as COSV67151211; called by mutect2, pindel, varscan2
- KIAA0319 | c.928A>G p.S310G | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs775337564; called by muse, mutect2, varscan2
- PIP4K2C | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs781565216; called by mutect2, varscan2
- USP53 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770795452; called by muse, mutect2, varscan2
- ADRA1A | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATRX | c.4749_4752del p.K1583Nfs*22 | Frame Shift Del (DEL) | VAF 49/114 reads (43%) | called by mutect2, pindel, varscan2
- DMAP1 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PCDHB15 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MOV10L1 | c.213G>T p.L71= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV53174520; called by muse, mutect2
- EPPIN | c.223+30C>A | Intron (SNP) | VAF 34/62 reads (55%) | catalogued as rs779401161; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055782 G>A | 3'Flank (SNP) | VAF 24/53 reads (45%) | catalogued as rs370609031; called by muse, mutect2, varscan2
- NR2F2 | chr15:96326328 C>A | 5'Flank (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- RPL30 | c.299-246T>C | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as rs751410479; called by muse, varscan2
